Somatic mutation profile of tumor specimen HTMCP-03-06-02426-01A (aliquot HTMCP-03-06-02426-01A-01D-10409) from CGCI case HTMCP-03-06-02426, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G1.
Specimen HTMCP-03-06-02426-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbad4a9f-51e8-4a2c-a8aa-270e80dbcf3b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02426-10A (Blood Derived Normal), aliquot HTMCP-03-06-02426-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e86b03f-8bb4-4b8c-a209-593043795b27

The open-access MAF lists 31 somatic variants for this specimen: 17 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 11, Nonsense Mutation 1, RNA 1, Splice Region 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 60/134 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.4579C>T p.R1527C | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766187969, COSV99053217; called by muse, mutect2, varscan2
- GRIN2C | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757323508; called by muse, mutect2, varscan2
- KIF24 | c.2446G>C p.D816H | Missense Mutation (SNP) | VAF 108/395 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs746087288; called by muse, mutect2, varscan2
- PAMR1 | c.2005G>A p.A669T (on ENST00000619888 / NM_001001991.3; = p.A686T on NM_015430.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs753541038; called by mutect2, varscan2
- PTPRK | c.2407C>T p.R803* (on ENST00000368215 / NM_001291984.2; = p.R804* on NM_002844.4) | Nonsense Mutation (SNP) | VAF 40/132 reads (30%) | catalogued as COSV100950798; called by muse, mutect2, varscan2
- PTPRQ | c.3472G>A p.E1158K (on ENST00000616559; = p.E1116K on NM_001145026.2) | Missense Mutation (SNP) | VAF 86/159 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1287865470, COSV57049829; called by muse, mutect2, varscan2
- SLC32A1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54145571; called by muse, mutect2, varscan2
- STARD9 | c.12116C>T p.P4039L | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs973568713, COSV51903533; called by muse, mutect2, varscan2
- TMEM145 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as rs915648670; called by muse, mutect2, varscan2
- TUBGCP6 | c.3706C>T p.R1236W | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.614); catalogued as rs202093025; called by muse, mutect2, varscan2
- EYS | c.7105C>A p.L2369M | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- KIAA1210 | c.3677C>T p.S1226F | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PARD3B | c.2932G>A p.G978R (on ENST00000406610 / NM_001302769.2; = p.G909R on NM_057177.7) | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.708); called by muse, mutect2
- PLXNA2 | c.3457G>A p.V1153I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PSMD11 | c.1074G>A p.K358= | Splice Region (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- THOC2 | c.1633A>G p.T545A | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ABCC6 | c.3162G>A p.T1054= | Silent (SNP) | VAF 98/153 reads (64%) | catalogued as rs374140753; called by muse, mutect2, varscan2
- COL4A1 | c.4899C>T p.L1633= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs760487355; called by muse, mutect2, varscan2
- CYP2D6 | c.852G>A p.G284= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV62243324; called by muse, mutect2, varscan2
- DIAPH2 | c.1959G>A p.E653= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs991240918; called by muse, mutect2, varscan2
- DNAH10 | c.11106C>A p.I3702= (on ENST00000409039; = p.I3641= on NM_207437.3) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs770239948, COSV68990889; called by muse, mutect2
- GLI3 | c.4104C>T p.H1368= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs780530149, COSV101229683; called by mutect2, varscan2
- KIF24 | c.3024G>C p.L1008= | Silent (SNP) | VAF 84/280 reads (30%) | called by muse, mutect2, varscan2
- NDOR1 | c.882C>T p.S294= | Silent (SNP) | VAF 5/37 reads (14%) | called by mutect2, varscan2
- PCDHB10 | c.1245C>T p.A415= | Silent (SNP) | VAF 52/313 reads (17%) | catalogued as COSV53383257; called by muse, mutect2, varscan2
- ROCK2 | c.3693G>A p.L1231= | Silent (SNP) | VAF 43/89 reads (48%) | catalogued as rs764352065; called by muse, mutect2, varscan2
- RYR1 | c.3312G>A p.A1104= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as rs1057521916; ClinVar: likely benign; called by muse, mutect2, varscan2
- CR786580.1 | n.1229G>A | RNA (SNP) | VAF 28/98 reads (29%) | catalogued as rs78537534; called by muse, varscan2
- DRP2 | c.-6G>T | 5'UTR (SNP) | VAF 40/101 reads (40%) | catalogued as COSV65809339; called by muse, mutect2, varscan2
- RARA | c.179-5459C>T | Intron (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
